Somatic mutation profile of tumor specimen 0DA694 from CCDI case PBBJRI, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Large cell medulloblastoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.9 years (5,072 days).
Specimen 0DA694: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75858bba-62d2-4c9c-a179-91b94521e834.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DA695 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/734c834d-ccf9-420c-82d4-f6bd48531584

The open-access MAF lists 31 somatic variants for this specimen: 14 protein-altering or splice-affecting, 8 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 8, Intron 7, 3'UTR 2, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CES1 | c.1079C>A p.P360Q | Missense Mutation (SNP) | VAF 86/242 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV100828709; called by muse, mutect2, varscan2
- CTIF | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); catalogued as rs148673663; called by muse, mutect2, varscan2
- ENAM | c.2965G>T p.D989Y | Missense Mutation (SNP) | VAF 141/668 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68536136; called by muse, mutect2, varscan2
- HIVEP1 | c.4361C>A p.T1454N | Missense Mutation (SNP) | VAF 198/399 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0.191); catalogued as COSV101045346; called by muse, mutect2, varscan2
- MUC12 | c.13355C>T p.S4452L (on ENST00000379442; = p.S4309L on NM_001164462.1) | Missense Mutation (SNP) | VAF 34/376 reads (9%) | SIFT deleterious (0); catalogued as rs777696015; called by muse, mutect2
- OVCH1 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 101/393 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.075); catalogued as rs139521215; called by muse, mutect2, varscan2
- PTPRH | c.2881C>T p.R961W | Missense Mutation (SNP) | VAF 64/251 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs777016596, COSV54742471; called by muse, mutect2, varscan2
- TP53 | c.691A>C p.T231P | Missense Mutation (SNP) | VAF 64/78 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52760462, COSV52826742, COSV53143060, COSV53214710; called by muse, varscan2
- ABI1 | c.1326G>A p.W442* | Nonsense Mutation (SNP) | VAF 66/343 reads (19%) | called by muse, mutect2, varscan2
- CST9 | c.238G>A p.D80N | Missense Mutation (SNP) | VAF 46/302 reads (15%) | SIFT tolerated (0.52); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PAK1IP1 | c.709T>C p.C237R | Missense Mutation (SNP) | VAF 107/550 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- PDS5B | c.511C>T p.Q171* | Nonsense Mutation (SNP) | VAF 64/350 reads (18%) | called by muse, mutect2, varscan2
- RARS1 | c.1030G>T p.D344Y | Missense Mutation (SNP) | VAF 103/350 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SPDYC | c.688C>G p.L230V | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT tolerated (0.51); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ALYREF | c.222C>T p.G74= | Silent (SNP) | VAF 88/416 reads (21%) | catalogued as rs1237802709; called by muse, mutect2, varscan2
- CHRND | c.132C>T p.P44= | Silent (SNP) | VAF 175/546 reads (32%) | called by muse, mutect2, varscan2
- GPATCH2 | c.1464A>T p.R488= | Silent (SNP) | VAF 117/533 reads (22%) | called by muse, mutect2, varscan2
- NFKB1 | c.2487C>T p.D829= (on ENST00000394820 / NM_001382627.1; = p.D830= on NM_003998.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 138/528 reads (26%) | called by muse, mutect2, varscan2
- SLC9A2 | c.2160C>G p.S720= | Silent (SNP) | VAF 108/464 reads (23%) | called by muse, mutect2, varscan2
- TMEM229A | c.720C>T p.D240= | Silent (SNP) | VAF 156/335 reads (47%) | called by muse, mutect2, varscan2
- TSPAN31 | c.540C>T p.L180= | Silent (SNP) | VAF 84/556 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.39495C>T p.S13165= (on ENST00000591111; = p.S5741= on NM_003319.4) | Silent (SNP) | VAF 89/373 reads (24%) | catalogued as rs368005198; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- AC125421.1 | n.1054+47A>G | Intron (SNP) | VAF 57/187 reads (30%) | called by muse, mutect2
- DOK4 | c.862+39G>A | Intron (SNP) | VAF 114/332 reads (34%) | called by muse, mutect2, varscan2
- DPP9 | c.2092-298A>G | Intron (SNP) | VAF 2/18 reads (11%) | called by muse, mutect2
- HP | c.442+40C>T | Intron (SNP) | VAF 123/339 reads (36%) | catalogued as rs570083636; called by muse, mutect2, varscan2
- ILF3 | c.1180+25C>T | Intron (SNP) | VAF 56/165 reads (34%) | called by muse, mutect2, varscan2
- PKP2 | c.2490-46A>G | Intron (SNP) | VAF 49/224 reads (22%) | catalogued as rs1422792186; called by muse, mutect2, varscan2
- TCHH | c.*91G>T | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, mutect2
- TMEM225B | c.*59T>G | 3'UTR (SNP) | VAF 28/136 reads (21%) | called by muse, mutect2, varscan2
- TSPAN31 | c.559-15C>T | Intron (SNP) | VAF 49/366 reads (13%) | called by muse, mutect2, varscan2
